Somatic mutation profile of tumor specimen TCGA-TM-A7CF-02A (aliquot TCGA-TM-A7CF-02A-11D-A32B-08) from TCGA case TCGA-TM-A7CF, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Astrocytoma, NOS; Tissue or organ of origin: Cerebrum; Tumor grade: G2; Age at diagnosis: 41.6 years (15,178 days).
Specimen TCGA-TM-A7CF-02A: Sample type: Recurrent Tumor; Tissue type: Tumor; Tumor descriptor: Recurrence.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ba337c4b-a910-4594-a637-961ad01f39fa.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-TM-A7CF-10A (Blood Derived Normal), aliquot TCGA-TM-A7CF-10A-01D-A329-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/28f0167d-6b5c-4ce6-93ea-01a26278dcbb

The open-access MAF lists 19 somatic variants for this specimen: 18 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 18, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 5/35 reads (14%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2
- TP53 | c.817C>T p.R273C | Missense Mutation (SNP) | VAF 9/27 reads (33%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913343, CM010471, CM010473, CM951233, COSV52662066, COSV52670856, COSV52707054, COSV53164203; ClinVar: not provided / uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2
- TP53 | c.643A>G p.S215G | Missense Mutation (SNP) | VAF 10/25 reads (40%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs886039484, CD1511147, COSV52675946, COSV52689203, COSV52876251, COSV53707934; ClinVar: conflicting interpretations of pathogenicity / likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- CELSR2 | c.6079T>C p.S2027P | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.925); catalogued as COSV99604320; called by muse, mutect2, varscan2
- DCDC1 | c.3284G>A p.S1095N (on ENST00000597505 / NM_001367979.1; = p.S202N on NM_020869.3) | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT tolerated (0.38); PolyPhen benign (0.04); catalogued as COSV100338503; called by muse, mutect2, varscan2
- FGA | c.1936G>T p.G646C | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV100120524; called by muse, mutect2, varscan2
- FLNA | c.4962C>A p.H1654Q | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.96); catalogued as COSV100774899; called by muse, mutect2, varscan2
- GMPPA | c.1224G>C p.K408N | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100354738; called by muse, mutect2, varscan2
- IQSEC1 | c.2482A>C p.T828P | Missense Mutation (SNP) | VAF 9/78 reads (12%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.506); catalogued as COSV99832095; called by muse, mutect2
- KRT81 | c.28C>T p.R10C | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.587); catalogued as rs753782485, COSV100576994; called by muse, mutect2, varscan2
- NRROS | c.1510G>A p.A504T | Missense Mutation (SNP) | VAF 25/83 reads (30%) | SIFT tolerated (0.76); PolyPhen benign (0.001); catalogued as rs139647726; called by muse, mutect2, varscan2
- OR52E4 | c.499C>T p.R167C | Missense Mutation (SNP) | VAF 22/80 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as rs757270158, COSV57623791, COSV57625916; called by muse, varscan2
- OTOS | c.95C>T p.A32V | Missense Mutation (SNP) | VAF 24/86 reads (28%) | SIFT tolerated (0.28); PolyPhen benign (0.062); catalogued as rs750554667, COSV56228628; called by muse, mutect2, varscan2
- PGLYRP2 | c.880C>T p.P294S | Missense Mutation (SNP) | VAF 3/44 reads (7%) | SIFT tolerated (0.12); PolyPhen benign (0.05); catalogued as COSV99484172; called by muse, mutect2
- RNF17 | c.2128A>G p.I710V | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.015); catalogued as rs368259164; called by muse, mutect2, varscan2
- THRAP3 | c.859C>G p.L287V | Missense Mutation (SNP) | VAF 14/95 reads (15%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as COSV100663459; called by muse, mutect2, varscan2
- TMEM14A | c.246G>C p.L82F | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.072); catalogued as COSV99276000; called by muse, varscan2
- ZBTB14 | c.976A>C p.I326L | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT tolerated (0.67); PolyPhen benign (0.099); catalogued as COSV100813477; called by muse, mutect2, varscan2
- RGS6 | c.1320C>T p.R440= | Silent (SNP) | VAF 8/102 reads (8%) | catalogued as COSV100666626; called by muse, mutect2
